Surgical pathology report (de-identified scan), TCGA case TCGA-4K-AA1H, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Proteogenex, Inc., specimen TCGA-4K-AA1H-01A (Primary Tumor).

Age/Sex: years / M

Date:

Procedure: Left orchiectomy

Preoperative diagnosis: TUMOR OF THE LEFT TESTIS

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LEFT TESTIS

Diagnosis:

1. LEFT TESTIS:

- Seminoma
- Tumor invades the tunica albuginea
- Vascular invasion is present
- Resection margin and epididymis are free of tumor

Gross description:

1. LEFT TESTIS:

Received fresh, is a left testis 5.5 x 4.5 x 3.5 cm in dimensions with a portion of the spermatic cord 10.0 cm in length. In the testis there is a firm gray tumor 2.5 x 2.3 x 2.0 cm in dimensions.

ICD-O-3

Seminoma NOS 9061/3

Site: ⊙ Testis NOS C62.9

9/11/27/14

Source: NCI Genomic Data Commons file 48e90c76-2137-4e6c-a019-70bed1579500 (TCGA-4K-AA1H.A8E19E8E-34B6-4CED-9EEF-A7EE88E0EA44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).